Somatic mutation profile of tumor specimen TARGET-50-PALJIP-01A (aliquot TARGET-50-PALJIP-01A-01D) from TARGET case TARGET-50-PALJIP, project TARGET-WT (High-Risk Wilms Tumor). Sex at birth: female; Vital status: Dead; Primary diagnosis: Wilms tumor; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 4.9 years (1,789 days).
Specimen TARGET-50-PALJIP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6929bf1c-f5d9-467d-9079-1bb7c340947d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-50-PALJIP-11A (Solid Tissue Normal), aliquot TARGET-50-PALJIP-11A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8bdf64f4-827f-48b4-8faa-fe8097e2a037

The open-access MAF lists 7 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 6, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CMTR1 | c.1370G>A p.R457Q | Missense Mutation (SNP) | VAF 114/474 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.431); catalogued as rs766423452, COSV65089743; called by muse, mutect2, varscan2
- ERC1 | c.194C>T p.A65V | Missense Mutation (SNP) | VAF 31/119 reads (26%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.463); catalogued as rs1232679465, COSV61692653; called by muse, mutect2, varscan2
- SCAMP4 | c.26C>T p.P9L | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763858621, COSV60190373; called by muse, mutect2, varscan2
- SYNJ2 | c.1915C>T p.R639C | Missense Mutation (SNP) | VAF 107/477 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747882037, COSV62896050; called by muse, mutect2, varscan2
- TRIB1 | c.551G>A p.R184Q | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.829); catalogued as rs150043688; called by muse, varscan2
- POLR3C | c.1441G>C p.E481Q | Missense Mutation (SNP) | VAF 23/755 reads (3%) | SIFT tolerated (0.25); PolyPhen benign (0.276); called by muse, mutect2
- PPP1R3A | c.597A>G p.Q199= | Silent (SNP) | VAF 48/550 reads (9%) | catalogued as rs761853557, COSV52885517; called by muse, mutect2
